Somatic mutation profile of tumor specimen MP2PRT-PAUYKL-TMP1-A (aliquot MP2PRT-PAUYKL-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAUYKL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,678 days).
Specimen MP2PRT-PAUYKL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec776748-e7a7-4583-9281-2cc0c86128fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUYKL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUYKL-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b25f12a8-2bb8-419d-a975-f3abda4b2bd6

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC1H1 | c.7351C>T p.R2451C | Missense Mutation (SNP) | VAF 330/830 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs1415287907; called by muse, mutect2, varscan2
- DYNC2H1 | c.3457C>T p.R1153W | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs544600765, COSV62091011; called by muse, mutect2
- LAMA1 | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 378/1166 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as rs748782379; called by muse, mutect2
- RPGR | c.1131C>G p.F377L | Missense Mutation (SNP) | VAF 318/360 reads (88%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58834226; called by muse, mutect2, varscan2
- DST | c.19523C>A p.T6508N (on ENST00000361203 / NM_001374722.1; = p.T4205N on NM_015548.5) | Missense Mutation (SNP) | VAF 291/677 reads (43%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- EFCAB13 | c.603G>C p.L201F | Missense Mutation (SNP) | VAF 141/521 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- FXYD1 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 26/810 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGHV1-58 | c.348_349insAGAGGAAAAA p.A117Rfs*? | Frame Shift Ins (INS) | VAF 13/48 reads (27%) | called by mutect2, pindel
- PLA1A | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 247/559 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNA4 | c.162C>T p.S54= | Silent (SNP) | VAF 467/1095 reads (43%) | catalogued as rs749000246, COSV60252647, COSV60253432, COSV60255384; called by muse, mutect2, varscan2
